Surgical pathology report (de-identified scan), TCGA case TCGA-E1-5322, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-5322-01A (Primary Tumor).

[page 1 of 2]
Clinical History:

Brain tumor.

Gross Examination:

A. "Brain tumor FS (AF1)", received fresh fro frozen section. A 4.5 x 3 x 1 cm aggregate of soft glistening gray-tan tissue is received. A portion of the specimen has been previously submitted as frozen section AF1. The frozen section remnant is submitted in A1. Representative is retained in formalin and the remainder is submitted in A2-3.

B. "Brain tumor", received fresh and placed in formalin. A 5.5 x 5.3 x 2.5 cm fragment of firm glistening gelatinous appearing tissue is received. Multiple representative submitted in B1-6.

Intraoperative Consultation:

A. "Brain tumor FS":AF1- glioma, probably high grade

Microscopic Examination:

The tissue is brain which is exhibits a densely cellular neoplasm composed of cells with round to irregular nuclei having dispersed, thread like chromatin exhibiting punctate chromocenters. Mitotic activity is exceptionally scanty. Microcysts are numerous and often filled with basophilic material. Focally the tumor is remarkable for extensive perineuronal satellitosis. In other areas the tumor exhibits more pleomorphic nuclear features and fibrillar cytoplasm. Tumor is remarkable diffusely for thin delicate arcuating vessels with no evidence of vascular proliferation seen. There is no evidence of necrosis.

DIAGNOSIS:

A. "BRAIN TUMOR":

WELL DIFFERENTIATED OLIGO-ASTROCYTOMA (WHO GRADE II).

B. "BRAIN TUMOR":

WELL DIFFERENTIATED OLIGO-ASTROCYTOMA (WHO GRADE II).

Continued on next page...

Page: 1

Patient:

MRN:

Location:

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Electronically signed

** END OF REPORT **

Page: 2

Patient:
HX No:
Location:

Source: NCI Genomic Data Commons file b6da8027-ce18-40c0-a0d2-f6ae00d2f553 (TCGA-E1-5322.68735214-8BFF-497F-8157-0EFF26A678F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).